Surgical pathology report (de-identified scan), TCGA case TCGA-G9-6361, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G9-6361-01A (Primary Tumor).

[page 1 of 3]
SPECIMENS:

- A. LEFT PELVIC LYMPH NODES
- B. RIGHT PELVIC LYMPH NODES
- C. PROSTATE

CGA - G9 - 6361

SPECIMEN(S):

- A. LEFT PELVIC LYMPH NODES
- B. RIGHT PELVIC LYMPH NODES
- C. PROSTATE

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

FSA. Left pelvic lymph nodes: Negative for carcinoma. By Dr. called to Dr.

FSB. Right pelvic lymph nodes: Negative for carcinoma. By Dr., called to Dr.

GROSS DESCRIPTION:

A. LEFT PELVIC LYMPH NODES

Received fresh are fragments of fibroadipose tissue with aggregate size of 4.0 x 4.0 x 0.7 cm. Multiple lymph nodes are dissected out of the fibroadipose tissue for intraoperative consultation. Representative three lymph nodes are submitted for frozen section and re-submitted in cassette A1. Remaining lymph nodes (six) are submitted in cassette A2.

B. RIGHT PELVIC LYMPH NODES

Received fresh are fragments of fibroadipose tissue measuring 3.0 x 1.0 x 1.0 cm. Multiple lymph nodes were dissected for frozen section diagnosis and re-submitted in cassette B1. Additional lymph nodes were also submitted in cassette B2.

C. PROSTATE

Received fresh is a 41 gram prostate measuring 4.8 cm from right to left, 3.5 cm from anterior to posterior, and 2.5 cm from apex to base, with attached right and left seminal vesicles and vas deferens. The capsule is tan pink smooth and intact. The specimen is inked as follows: Anterior-Orange, Posterior-Black, Apex-Red, Base-Blue, Right-Green, Left-Yellow. After removal of the apex and base, the remaining prostate weight is 21g. The specimen is serially sectioned from apex to base to reveal firm tan fibrous parenchyma. No obvious lesions or nodules are grossly identified. The attached right and left seminal vesicles are 3.4 x 1 x 0.8 cm and 3.5 x 2 x 2 cm, respectively, are sectioned to beige tan cystic tissue with no gross evidence of tumor involvement. The attached right and left segments of vas deferens are 3 x 0.7 cm and 5 x 0.4 cm, respectively, are sectioned to reveal firm tan tubular structure with no gross evidence of tumor involvement. A portion of the specimen is submitted for tissue procurement (Level II). The remainder of the specimen is submitted as follows:

- C1-2: right apex
- C3-4: left apex
- C5: Level I right anterior
- C6-C7: Level I right posterior
- C8-C9: Level I left anterior
- C10-C12: Level I left posterior
- C13: Level II right anterior capsule
- C14: Level II right posterior capsule
- C15: Level II left anterior capsule
- C16: Level II left posterior capsule
- C17-C18: right base with periurethral margin
- C19: left base with periurethral margin
- C20: right lateral base
- C21: left lateral base
- C22: right base
- C23: left base
- C24: right seminal vesicle and vas deferens
- C25: left seminal vesicle and vas deferens

DIAGNOSIS:

A. PROSTATE, RADICAL PROSTATECTOMY:

- ADENOCARCINOMA INVOLVING RIGHT, LEFT, ANTERIOR, POSTERIOR, APICAL, AND BASAL ASPECTS AND 25% OF THE EVALUATED PROSTATIC TISSUE
- GLEASON#S GRADE 3 + 4 (SCORE 7/10)

[page 2 of 3]
-
- EXTENSIVE MULTIFOCAL LEFT ANTERIOR AND POSTERIOR AND LEFT BASE
EXTRAPROSTATIC FAT INVOLVEMENT SEEN
- LEFT LATERAL BASE CAUTERIZED SURGICAL MARGIN MICROSCOPICALLY POSITIVE FOR
CARCINOMA (SEE NOTE)
- SEE SYNOPTIC REPORT

NOTE: There is microscopic focus of cauterized carcinomatous glands (less than 1 mm) seen at the inked cauterized margin in the left lateral base location. Correlation with clinical and surgical findings is recommended. Dr. has seen representative slides of this case. Verbal report was given to Dr.

SYNOPTIC REPORT - PROSTATE GLAND

Location: Left
Right
Posterior lateral
Apical
Basal
Anterior
WHO CLASSIFICATION
Epithelial tumors
Adenocarcinoma 8140/3
Multicentricity: Yes
Gland Involvement: 25%
Gleason Grade/Sum:: Grade 3 + 4 , Sum 7
High Grade PIN Present: Yes
Perineural Invasion: Yes
Vascular/Lymphatic Invasion: No
Seminal Vesicle Invasion: No
Periprostatic Fat Involved: Yes
Details: Left anterior and posterior and left base
Bladder Neck Involved: No
Margins Involvement: Yes
Location: left lateral base
Linear Distance: Microscopic (<1mm)
Frozen Performed: Yes
Post Hormonal Therapy Change: No
Lymph Nodes: Negative Right 0 / 5 Left 0 / 7
Other Pathologic Findings: BPH
acute and chronic inflammation
Pathological Staging (pTNM): T 3a N 0 M x

CLINICAL HISTORY:

None provided

PRE-OPERATIVE DIAGNOSIS:

Prostate Ca

ADDENDUM:

This addendum is issued to add additional diagnostic information in regard to specimens A and B, labeled "LEFT AND RIGHT PELVIC LYMPH NODES", respectively. The "RADICAL PROSTATECTOMY" specimen reported above should be labeled "C".

A. LYMPH NODE, LEFT PELVIC, EXCISION:
- NO TUMOR SEEN IN SEVEN LYMPH NODES (0/7)

B. LYMPH NODE, RIGHT PELVIC, EXCISION:
- NO TUMOR SEEN IN FIVE LYMPH NODES (0/5)

[page 3 of 3]
[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 124f01fe-d910-4e8c-a07c-08878c27aeca (TCGA-G9-6361.49FE865A-79E8-4FF3-A52E-9888C4514CF2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).